MMRF case MMRF_2427 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8b6875ae-0e75-4d66-a5c4-ab88cc8da9e6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 638 days (1.7 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.8 years (23,662 days); ISS stage: II; Days to last known disease status: 638 days (1.7 years); Days to last follow up: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 235 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 306 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 246 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 180 days; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 246 days; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 344 days; Days to treatment end: 398 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 344 days; Days to treatment end: 370 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 371 days (1.0 years); Days to treatment end: 398 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 446 days (1.2 years); Days to treatment end: 554 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 638.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 2.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 73.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 37.3 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.01 g/L; Beta 2 Microglobulin 4.54 µg/mL; Lactate Dehydrogenase 10.4 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 39 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 8 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.32 mg/dL.
- Day 103 (ECOG 0): M Protein 1.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 297 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.146 mg/dL; Immunoglobulin G 24.2 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 1.4 ×10⁹/L; Absolute Neutrophil 0.3 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 4.35 mmol/L.
- Day 187 (ECOG 0): M Protein 2.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 286 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.471 mg/dL; Immunoglobulin G 27.3 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.61 µg/mL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 53 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 7.6 g/dL; Glucose 4.73 mmol/L.
- Day 302 (ECOG 2): M Protein 1.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 122 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.734 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.08 µg/mL; Lactate Dehydrogenase 4.4 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 34.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.08 mmol/L; Albumin 28 g/L; Total Protein 6 g/dL; Glucose 5.12 mmol/L.
- Day 371: M Protein 1.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.754 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.93 µg/mL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 32 ×10⁹/L; Creatinine 40.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 4.07 mmol/L.
- Day 460 (ECOG 1): M Protein 1.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 290 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.469 mg/dL; Immunoglobulin G 20.9 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 3.37 µg/mL; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 541 (ECOG 1): M Protein 1.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 252 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.209 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 1.71 µg/mL; Lactate Dehydrogenase 4.15 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 49 ×10⁹/L; Creatinine 37.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.1 mmol/L; Albumin 28 g/L; Total Protein 5.7 g/dL; Glucose 4.4 mmol/L.
- Day 610 (ECOG 3): Lactate Dehydrogenase 13.6 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 6.53 ×10⁹/L; Platelets 21 ×10⁹/L; Creatinine 26.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 1.75 mmol/L; Total Protein 5.9 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day 1: Weight: 68 kg; Height: 157 cm.

Biospecimens (2 samples)
- Sample MMRF_2427_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2427_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
